Somatic mutation profile of tumor specimen TCGA-3B-A9HR-01A (aliquot TCGA-3B-A9HR-01A-11D-A387-09) from TCGA case TCGA-3B-A9HR, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 38.4 years (14,041 days).
Specimen TCGA-3B-A9HR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a573342f-f576-47aa-b660-6b901883874d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-3B-A9HR-10A (Blood Derived Normal), aliquot TCGA-3B-A9HR-10A-01D-A38A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b6b5da37-6384-4314-abf9-6017ac172877

The open-access MAF lists 25 somatic variants for this specimen: 22 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 21, Silent 3, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BPIFC | c.358T>A p.F120I | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV100300655; called by muse, mutect2, varscan2
- CEP290 | c.2909A>G p.N970S | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as rs951200727, COSV100467550; called by muse, mutect2, varscan2
- CORO7 | c.1619C>T p.T540M | Missense Mutation (SNP) | VAF 37/111 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200682379, COSV99227020; called by muse, mutect2, varscan2
- CTNNA2 | c.2018C>T p.A673V | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.837); catalogued as COSV58152383; called by muse, mutect2, varscan2
- ERICH3 | c.4127C>G p.S1376C | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV100443101; called by muse, mutect2, varscan2
- F2R | c.887G>T p.C296F | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100058248; called by muse, mutect2, varscan2
- GATA3 | c.812C>A p.T271N | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM096030, COSV100650748; called by muse, mutect2, varscan2
- GBA | c.1027T>A p.Y343N | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100516174; called by muse, mutect2, varscan2
- IGLV1-36 | c.333G>T p.W111C | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.886); catalogued as rs1275445102; called by muse, mutect2, varscan2
- MUC17 | c.2417C>A p.P806H | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV100071115, COSV60286491; called by muse, mutect2, varscan2
- NPAS3 | c.2458G>A p.A820T (on ENST00000356141 / NM_001164749.2; = p.A788T on NM_022123.3) | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.062); catalogued as COSV100639239; called by muse, mutect2, varscan2
- OR6C1 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.066); catalogued as rs143845104; called by muse, mutect2, varscan2
- PRH2 | c.82G>A p.V28I | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.208); catalogued as rs776898585, COSV67171669; called by muse, mutect2, varscan2
- PRMT2 | c.1171G>A p.G391S | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV99388391; called by muse, mutect2, varscan2
- SLC35G1 | c.185A>G p.K62R (on ENST00000427197 / NM_001134658.3; = p.K61R on NM_153226.4) | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as rs542280075, COSV101003999; called by muse, mutect2, varscan2
- SLCO1B1 | c.613T>C p.S205P | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV99917792; called by muse, mutect2, varscan2
- SRR | c.709G>T p.A237S | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100026796; called by muse, mutect2
- ST3GAL5 | c.188T>C p.L63S | Missense Mutation (SNP) | VAF 41/118 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.945); catalogued as COSV100088144; called by muse, mutect2, varscan2
- TDRD7 | c.2060A>G p.E687G | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100795401; called by muse, mutect2, varscan2
- TJP1 | c.5084G>C p.S1695T | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100632146; called by muse, mutect2, varscan2
- TP63 | c.1400A>G p.N467S | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.024); catalogued as rs369453583; called by muse, mutect2, varscan2
- TSHZ2 | c.1722del p.K574Nfs*2 | Frame Shift Del (DEL) | VAF 9/40 reads (23%) | called by mutect2, pindel, varscan2
- CRACD | c.1014C>T p.D338= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as rs1403508866, COSV99948331; called by mutect2, varscan2
- DIP2A | c.696G>C p.V232= | Silent (SNP) | VAF 21/99 reads (21%) | catalogued as COSV100594984; called by muse, mutect2, varscan2
- ZNF607 | c.1386A>G p.S462= | Silent (SNP) | VAF 24/98 reads (24%) | catalogued as rs1381307019, COSV100777788; called by muse, mutect2
